Somatic mutation profile of tumor specimen TCGA-22-4613-01A (aliquot TCGA-22-4613-01A-01D-1441-08) from TCGA case TCGA-22-4613, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.2 years (26,722 days).
Specimen TCGA-22-4613-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6076790f-ed57-47d3-ae1a-211164bb87ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4613-11A (Solid Tissue Normal), aliquot TCGA-22-4613-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d0099d-70c3-4265-8f49-a38348314636

The open-access MAF lists 689 somatic variants for this specimen: 522 protein-altering or splice-affecting, 150 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 447, Silent 150, Nonsense Mutation 30, Frame Shift Del 20, Splice Site 10, Splice Region 8, Frame Shift Ins 6, Intron 6, 5'Flank 3, 5'UTR 3, RNA 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGF23 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs104894347, CM002776, COSV52976124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 89/262 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.768); catalogued as COSV51759856; called by muse, mutect2, varscan2
- ABAT | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51624127; called by muse, mutect2, varscan2
- ABCA6 | c.4162G>C p.D1388H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV52639698, COSV52647205; called by muse, mutect2, varscan2
- ABCC8 | c.3366C>A p.N1122K | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56851732; called by muse, mutect2, varscan2
- ABCF1 | c.2048G>T p.R683I (on ENST00000326195 / NM_001025091.2; = p.R645I on NM_001090.3) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV58229399; called by muse, mutect2, varscan2
- ACRV1 | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV59755027; called by muse, mutect2, varscan2
- ACSM5 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV59370126, COSV59372077; called by muse, mutect2, varscan2
- ACTR10 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1261887073, COSV54298697; called by muse, mutect2, varscan2
- ADAM11 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.881); catalogued as COSV52346907; called by muse, mutect2, varscan2
- ADAM18 | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.21); catalogued as COSV55845833, COSV55848649; called by muse, mutect2, varscan2
- ADAM2 | c.1453A>T p.I485L | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV55863295; called by muse, mutect2, varscan2
- ADAM22 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as COSV55978902; called by muse, mutect2, varscan2
- ADAMTS12 | c.3443C>A p.T1148N | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV61256251, COSV61263358; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as COSV58443778, COSV58444166; called by muse, mutect2
- ADCYAP1R1 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV58444172; called by muse, mutect2, varscan2
- ADGRL3 | c.2122G>C p.E708Q (on ENST00000506720 / NM_001322402.2; = p.E640Q on NM_015236.6) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.34); catalogued as COSV72230810; called by muse, mutect2, varscan2
- ADSS1 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1432636140, COSV58273919; called by muse, mutect2, varscan2
- ALK | c.3335C>A p.P1112Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101202412; called by muse, mutect2
- AMTN | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59489169; called by muse, mutect2, varscan2
- ANK3 | c.10501C>T p.Q3501* | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as COSV55061726; called by muse, mutect2, varscan2
- ANKRD12 | c.342A>T p.E114D | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs866962789, COSV50827974; called by muse, mutect2, varscan2
- ANKS1B | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61355078; called by muse, mutect2, varscan2
- ANO6 | c.1105-1G>C p.X369_splice | Splice Site (SNP) | VAF 67/229 reads (29%) | catalogued as COSV57662165; called by muse, mutect2, varscan2
- AOC3 | c.1510A>T p.T504S | Missense Mutation (SNP) | VAF 100/150 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53827129; called by muse, mutect2, varscan2
- AP002512.3 | c.1017G>C p.K339N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175105672, COSV54407018; called by muse, mutect2, varscan2
- APAF1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1414974149, COSV54489892; called by muse, mutect2, varscan2
- APEX2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as COSV100895161, COSV66624075; called by muse, mutect2, varscan2
- ARHGEF17 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs771901239, COSV55233291; called by muse, mutect2, varscan2
- ARMC3 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV53062435; called by muse, mutect2, varscan2
- ART3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs142545952; called by muse, mutect2, varscan2
- ASB5 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV56671663; called by muse, mutect2, varscan2
- ASCL4 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV60816772; called by muse, mutect2, varscan2
- ATG3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV51927126; called by muse, mutect2, varscan2
- ATP12A | c.676T>G p.C226G | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54517724; called by muse, mutect2, varscan2
- ATP12A | c.2825T>C p.L942P | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV54517732; called by muse, mutect2, varscan2
- ATP13A4 | c.1901G>T p.C634F | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55066495; called by muse, mutect2, varscan2
- ATP8A1 | c.3009G>A p.W1003* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV52536923; called by muse, mutect2, varscan2
- ATPSCKMT | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV54726964, COSV54727340; called by muse, mutect2, varscan2
- ATR | c.6859C>A p.P2287T | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV63387298; called by muse, mutect2, varscan2
- ATRX | c.3945A>G p.E1315= | Splice Region (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64877910; called by muse, mutect2, varscan2
- BCL11A | c.989A>T p.Q330L (on ENST00000335712 / NM_001365609.1; = p.Q364L on NM_018014.4) | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV59631263; called by muse, mutect2
- BEND2 | c.2218C>A p.L740I | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66220990; called by muse, mutect2, varscan2
- BEND4 | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101549700, COSV72469149; called by muse, mutect2, varscan2
- BICRAL | c.1811C>G p.T604R | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV58406169; called by muse, mutect2, varscan2
- BPTF | c.2673G>T p.W891C | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58838603; called by muse, mutect2, varscan2
- BRCA1 | c.4993G>T p.V1665L | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58791696; called by muse, mutect2, varscan2
- BRINP3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs144952455, COSV66521744; called by muse, mutect2, varscan2
- BRPF3 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 42/188 reads (22%) | catalogued as COSV100326019, COSV60206265; called by muse, varscan2
- BRWD3 | c.2044+2T>A p.X682_splice | Splice Site (SNP) | VAF 20/107 reads (19%) | catalogued as COSV64749095; called by muse, mutect2, varscan2
- C10orf90 | c.1991A>T p.K664M | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52956719; called by muse, mutect2, varscan2
- C4B | c.3593A>G p.Y1198C | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754182832, COSV70313463; called by muse, mutect2, varscan2
- C6 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as COSV54711520; called by muse, mutect2, varscan2
- CACNA1C | c.5136C>A p.S1712R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.979); catalogued as COSV100222499, COSV59727607; called by muse, mutect2, varscan2
- CACNA2D4 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54951594; called by muse, mutect2, varscan2
- CALCR | c.985T>G p.F329V (on ENST00000649521 / NM_001164737.2; = p.F313V on NM_001742.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV64008786; called by muse, mutect2, varscan2
- CASR | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV56138268; called by muse, mutect2
- CBLL1 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.923); catalogued as COSV56029133; called by muse, mutect2, varscan2
- CC2D1A | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV58784018; called by muse, mutect2, varscan2
- CCDC178 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55767682, COSV55777072; called by muse, mutect2
- CCDC190 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV63363018; called by muse, mutect2, varscan2
- CCNB3 | c.3755T>A p.L1252H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52074629; called by muse, mutect2, varscan2
- CD163L1 | c.1868A>G p.Q623R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58017594; called by muse, mutect2, varscan2
- CDH10 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100051622, COSV52575233, COSV52579534; called by muse, mutect2, varscan2
- CDH9 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 141/275 reads (51%) | catalogued as rs113264250, COSV50298580; called by muse, mutect2, varscan2
- CELSR2 | c.8018del p.G2673Afs*12 | Frame Shift Del (DEL) | VAF 34/161 reads (21%) | catalogued as COSV54767659; called by mutect2, pindel, varscan2
- CERS1 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.209); catalogued as COSV55929551; called by muse, mutect2, varscan2
- CFAP206 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV51534690; called by muse, mutect2, varscan2
- CFHR4 | c.1729G>T p.E577* (on ENST00000367416 / NM_001201551.2; = p.E331* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 46/206 reads (22%) | catalogued as COSV52230105; called by muse, mutect2, varscan2
- CIZ1 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV99476999; called by muse, mutect2, varscan2
- CLEC14A | c.1005A>C p.E335D | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as COSV60562778; called by muse, mutect2, varscan2
- CNTNAP4 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs151315964, COSV56692426; called by muse, mutect2, varscan2
- CNTNAP4 | c.3686G>T p.R1229I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV56673456; called by muse, mutect2, varscan2
- COL21A1 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV55165760; called by muse, mutect2, varscan2
- COL24A1 | c.3613C>G p.P1205A | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV65307731; called by muse, mutect2, varscan2
- COL4A1 | c.4240G>T p.G1414W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65430705; called by muse, mutect2, varscan2
- COL5A2 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV66410502; called by muse, mutect2, varscan2
- COL6A5 | c.5987C>T p.A1996V (on ENST00000312481; = p.A1992V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV55204825, COSV99593286; called by muse, mutect2, varscan2
- COL6A6 | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100649746, COSV62027245; called by muse, mutect2, varscan2
- CPA3 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56045526; called by muse, mutect2, varscan2
- CPNE3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781107778, COSV52206955; called by muse, mutect2, varscan2
- CPXM1 | c.1622T>A p.L541Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV66045635; called by muse, mutect2, varscan2
- CRB1 | c.1672A>T p.I558F | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs115811272, COSV66330985; called by muse, mutect2, varscan2
- CSMD1 | c.3889G>T p.A1297S (on ENST00000520002; = p.A1296S on NM_033225.6) | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.439); catalogued as COSV59333941; called by muse, mutect2, varscan2
- CSMD3 | c.7279T>A p.F2427I (on ENST00000297405 / NM_001363185.1; = p.F2323I on NM_052900.3) | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52111825; called by muse, mutect2, varscan2
- CTAG2 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.953); catalogued as COSV55995205; called by muse, mutect2
- CTAGE1 | c.1565G>T p.R522L | Missense Mutation (SNP) | VAF 73/536 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV66943238; called by muse, mutect2, varscan2
- CTNNA2 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63573484; called by muse, varscan2
- CTNNA3 | c.2282G>T p.C761F | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65525203; called by muse, mutect2, varscan2
- CUBN | c.6449G>T p.G2150V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64717728, COSV64722860; called by muse, mutect2, varscan2
- CXXC4 | c.1075A>T p.S359C | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV67296461; called by muse, mutect2, varscan2
- CXorf65 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV52148702; called by muse, mutect2, varscan2
- CXorf66 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV65169351; called by muse, mutect2, varscan2
- CYP19A1 | c.540T>A p.N180K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV53059837; called by muse, mutect2, varscan2
- CYP1A1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV65697415; called by muse, mutect2, varscan2
- CYP4F8 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1482386649, COSV57853388; called by muse, mutect2, varscan2
- DACH2 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64167175, COSV64171496; called by muse, mutect2, varscan2
- DCAF12L1 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64421963, COSV64422100; called by muse, mutect2, varscan2
- DCAF12L1 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV64421966, COSV64422026; called by muse, mutect2, varscan2
- DCHS1 | c.5650G>C p.A1884P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV55036651; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 59/184 reads (32%) | catalogued as COSV101373865, COSV69362732; called by pindel, varscan2
- DDB1 | c.2664G>A p.V888= | Splice Region (SNP) | VAF 31/117 reads (26%) | catalogued as COSV57103371; called by muse, mutect2, varscan2
- DDX19A | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1165311702, COSV56360127; called by muse, mutect2, varscan2
- DGCR8 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61226997; called by muse, mutect2, varscan2
- DHRS2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs780585174, COSV51632336; called by muse, mutect2, varscan2
- DHRS2 | c.540G>T p.V180= | Splice Region (SNP) | VAF 53/170 reads (31%) | catalogued as COSV51632359; called by muse, mutect2, varscan2
- DISP1 | c.4456A>T p.I1486F | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV52660217; called by muse, mutect2, varscan2
- DMD | c.8353A>T p.K2785* | Nonsense Mutation (SNP) | VAF 51/175 reads (29%) | catalogued as CM098451, COSV58916856; called by muse, mutect2, varscan2
- DMXL2 | c.7868T>C p.V2623A | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.05); catalogued as COSV51848048; called by muse, mutect2, varscan2
- DNAH1 | c.8026G>T p.D2676Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV70229943; called by muse, mutect2, varscan2
- DNAH11 | c.7656G>C p.E2552D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV60959738; called by muse, mutect2, varscan2
- DNAH8 | c.5813A>T p.D1938V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV59452502; called by muse, mutect2, varscan2
- DPP10 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59665720; called by muse, mutect2, varscan2
- DPP4 | c.2092G>T p.V698F | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758441966, COSV62107218; called by muse, mutect2, varscan2
- DRD2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV60758811; called by muse, mutect2, varscan2
- DRGX | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV65136434; called by muse, mutect2, varscan2
- DSG4 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as COSV57392743; called by muse, mutect2, varscan2
- DST | c.11786A>T p.D3929V (on ENST00000361203 / NM_001374722.1; = p.D1517V on NM_015548.5) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as COSV55019221; called by muse, mutect2, varscan2
- EIF3H | c.649del p.E217Nfs*30 | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | catalogued as COSV52669663; called by mutect2, pindel*, varscan2
- ELF4 | c.929C>G p.T310R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57452972; called by muse, mutect2
- EMILIN1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV53155157; called by muse, mutect2, varscan2
- EPHA5 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56649462; called by muse, mutect2, varscan2
- EPX | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99836646; called by muse, mutect2, varscan2
- ERAP2 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV65939988; called by muse, mutect2, varscan2
- ERCC6L | c.2531A>G p.Q844R | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV57820941; called by muse, mutect2, varscan2
- F5 | c.4141C>A p.Q1381K | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV63124919; called by muse, mutect2, varscan2
- FAM13C | c.1076C>G p.P359R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV53249848; called by muse, mutect2, varscan2
- FAM155A | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101029225; called by muse, mutect2, varscan2
- FAT3 | c.6364G>C p.V2122L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53121181, COSV99968356; called by muse, mutect2
- FBXW9 | c.1187G>T p.G396V (on ENST00000587955; = p.G376V on NM_032301.3) | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs62108390, COSV66709912; called by muse, mutect2, varscan2
- FGF5 | c.143A>C p.Q48P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56890445; called by muse, mutect2, varscan2
- FMN1 | c.3782T>G p.V1261G (on ENST00000616417 / NM_001277313.2; = p.V1038G on NM_001103184.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57924801; called by muse, mutect2, varscan2
- FRAS1 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV53616790; called by muse, mutect2, varscan2
- FRMPD1 | c.4322G>A p.G1441E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV66699747; called by muse, mutect2, varscan2
- FRY | c.2659G>T p.V887L | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66571669; called by muse, mutect2, varscan2
- FRY | c.4797G>C p.L1599F | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.197); catalogued as COSV66571674; called by muse, mutect2, varscan2
- FRY | c.6475C>A p.P2159T | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66565383, COSV66571682; called by muse, mutect2, varscan2
- FRZB | c.118A>T p.I40F | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54554410; called by muse, mutect2, varscan2
- FSTL5 | c.1351G>T p.G451W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60199779; called by muse, mutect2, varscan2
- FUNDC2 | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65671081; called by muse, mutect2
- GALNT6 | c.1847A>C p.H616P | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV62542429; called by muse, mutect2, varscan2
- GDF3 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1239441863, COSV61712814; called by muse, mutect2, varscan2
- GET4 | c.173A>T p.K58M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56255008; called by muse, mutect2
- GLP2R | c.782G>C p.R261P | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52325697; called by muse, mutect2, varscan2
- GLRA4 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV60327413, COSV60327781; called by muse, varscan2
- GLRA4 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV60327787; called by muse, varscan2
- GNPAT | c.1283A>C p.N428T | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV64153593; called by muse, mutect2, varscan2
- GP2 | c.802G>C p.E268Q (on ENST00000381362 / NM_001007240.3; = p.E265Q on NM_001502.4) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56894470; called by muse, mutect2, varscan2
- GPAA1 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60155654, COSV60155895; called by muse, mutect2, varscan2
- GPHB5 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs775865267, COSV58486271; called by muse, mutect2, varscan2
- GPR137B | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63991047; called by muse, mutect2, varscan2
- GPR156 | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 52/168 reads (31%) | catalogued as COSV59940467; called by muse, mutect2, varscan2
- GPR50 | c.552C>A p.N184K | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV54439550; called by muse, mutect2, varscan2
- GPT2 | c.996G>C p.E332D | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60838946; called by muse, mutect2, varscan2
- GRAMD2B | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53508062; called by muse, mutect2, varscan2
- GRAP2 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs147808667, COSV59995565; called by muse, mutect2, varscan2
- GREM2 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV58952038, COSV58958071; called by muse, mutect2, varscan2
- GRIA1 | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs1211344811, COSV53606676; called by muse, mutect2, varscan2
- GRIN2A | c.2432A>T p.Q811L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58037199; called by muse, mutect2, varscan2
- GRIN2B | c.3352G>T p.D1118Y | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV74206228; called by muse, mutect2, varscan2
- GRIN2B | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV74206229; called by muse, mutect2, varscan2
- GRIP2 | c.329C>A p.A110E (on ENST00000619221; = p.A13E on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as COSV56122058; called by muse, mutect2, varscan2
- GRM1 | c.3343C>G p.R1115G | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.02); catalogued as COSV51163890; called by muse, mutect2, varscan2
- GRM8 | c.1662A>T p.E554D | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV58832091; called by muse, mutect2, varscan2
- GRXCR1 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs372995631; called by muse, mutect2, varscan2
- GSS | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53625299; called by muse, mutect2, varscan2
- HAPLN4 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52269915; called by muse, mutect2, varscan2
- HBE1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV53080251; called by muse, mutect2, varscan2
- HBG2 | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100400668; called by muse, mutect2, varscan2
- HCFC2 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558854; called by muse, mutect2, varscan2
- HEPH | c.1188G>T p.M396I (on ENST00000343002; = p.M129I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100295201, COSV57958565; called by muse, mutect2, varscan2
- HLCS | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV60794387; called by muse, mutect2
- HNRNPM | c.1412G>C p.R471P | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55314213; called by muse, mutect2, varscan2
- HOXD4 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV60460024; called by muse, mutect2, varscan2
- HPSE | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV60987122; called by muse, mutect2, varscan2
- HSPA2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55969978, COSV99904841; called by muse, mutect2, varscan2
- HTR1A | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as rs1426563131, COSV60501186; called by muse, mutect2, varscan2
- IFNGR1 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62989915; called by muse, mutect2, varscan2
- IGDCC4 | c.3114C>A p.D1038E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61537432; called by muse, mutect2, varscan2
- IGHV3-15 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs552110714; called by muse, mutect2, varscan2
- IGSF1 | c.2932A>T p.S978C | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63837979; called by muse, mutect2
- IGSF10 | c.1589T>C p.I530T | Missense Mutation (SNP) | VAF 204/467 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56786387; called by muse, mutect2, varscan2
- IGSF11 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs554488208, COSV61171116; called by muse, mutect2, varscan2
- ITGA8 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65229946; called by muse, mutect2, varscan2
- ITGAD | c.2755T>C p.Y919H | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66758382; called by muse, mutect2, varscan2
- ITGB2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV56610349, COSV56610568; called by muse, mutect2, varscan2
- ITPKC | c.1255+1G>T p.X419_splice | Splice Site (SNP) | VAF 61/149 reads (41%) | catalogued as COSV54575334; called by muse, mutect2, varscan2
- JADE3 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV54467095; called by muse, mutect2, varscan2
- KANK1 | c.1834G>T p.D612Y | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as COSV63212742; called by muse, mutect2, varscan2
- KCNG4 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs1327492442, COSV57584196; called by muse, mutect2, varscan2
- KCNH3 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs188303067, COSV57791212; called by muse, mutect2, varscan2
- KCNQ3 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.715); catalogued as COSV66472608; called by muse, mutect2, varscan2
- KDR | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 29/117 reads (25%) | catalogued as COSV55758016; called by muse, mutect2, varscan2
- KIAA0408 | c.1513A>T p.M505L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100846988; called by muse, mutect2, varscan2
- KIF25 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1402807650, COSV63027600; called by muse, mutect2, varscan2
- KIFBP | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV62831835; called by muse, mutect2, varscan2
- KLHL4 | c.1606T>A p.Y536N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs202017331, COSV64143369; called by muse, mutect2, varscan2
- KRT85 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as rs1272408404, COSV57737162; called by muse, varscan2
- KRTAP4-4 | c.73T>A p.Y25N | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV66811354; called by muse, mutect2, varscan2
- KRTAP5-11 | c.171T>A p.C57* | Nonsense Mutation (SNP) | VAF 83/311 reads (27%) | catalogued as COSV59369635; called by muse, mutect2, varscan2
- KTN1 | c.4030C>A p.Q1344K (on ENST00000395314 / NM_001271014.2; = p.Q1287K on NM_004986.4) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV58540488; called by muse, mutect2, varscan2
- LAMA4 | c.4051A>T p.K1351* (on ENST00000230538 / NM_001105206.3; = p.K1344* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as COSV57898526; called by muse, mutect2, varscan2
- LATS1 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53592111; called by muse, mutect2, varscan2
- LCTL | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs755614665, COSV57180707; called by muse, mutect2, varscan2
- LGSN | c.1069T>A p.C357S | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV65727440; called by muse, mutect2, varscan2
- LILRA2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52192478; called by muse, mutect2, varscan2
- LILRB3 | c.1910A>G p.Y637C (on ENST00000346401; = p.Y625C on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54437467; called by muse, mutect2, varscan2
- LILRB5 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as COSV100300807, COSV60258098; called by muse, mutect2, varscan2
- LPA | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV60303176; called by muse, mutect2, varscan2
- LRCH2 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57752255; called by muse, mutect2, varscan2
- LRP1B | c.10081_10082insT p.R3361Lfs*17 | Frame Shift Ins (INS) | VAF 34/139 reads (24%) | catalogued as COSV101258197; called by mutect2, pindel, varscan2
- LRP1B | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV67230117, COSV67269582; called by muse, mutect2, varscan2
- LRP5 | c.4714C>A p.P1572T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53717142; called by muse, mutect2, varscan2
- LRRC4C | c.842T>A p.L281* | Nonsense Mutation (SNP) | VAF 60/222 reads (27%) | catalogued as COSV53427716; called by muse, mutect2, varscan2
- LRRIQ1 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.72); catalogued as rs1332312242, COSV67832027; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58186821; called by muse, mutect2, varscan2
- MAEL | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63305316; called by muse, mutect2, varscan2
- MAGEC3 | c.1706G>T p.W569L | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100025959; called by muse, mutect2
- MAP3K11 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58420090; called by muse, mutect2, varscan2
- MAP7D3 | c.2475A>T p.E825D | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV60171234; called by muse, mutect2, varscan2
- MCF2L2 | c.2045+1G>T p.X682_splice | Splice Site (SNP) | VAF 200/376 reads (53%) | catalogued as rs765616800, COSV61054877; called by muse, mutect2, varscan2
- MCM3AP | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV52440687; called by muse, mutect2
- MED12L | c.1325G>T p.W442L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56381571; called by muse, mutect2, varscan2
- MEOX2 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV56290789; called by muse, mutect2, varscan2
- MERTK | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 130/494 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV54930380, COSV54937416; called by muse, mutect2
- MEX3A | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV68478995, COSV68479139; called by muse, mutect2, varscan2
- MIB1 | c.2129A>T p.H710L | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV55091333; called by muse, mutect2, varscan2
- MICAL3 | c.3559G>T p.A1187S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV71588550; called by muse, mutect2, varscan2
- MIPEP | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs749656281, COSV66300848; called by muse, mutect2, varscan2
- MORF4L2 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64611059; called by muse, mutect2, varscan2
- MPC1 | c.172+1G>A p.X58_splice | Splice Site (SNP) | VAF 70/245 reads (29%) | catalogued as COSV59133011; called by muse, mutect2, varscan2
- MS4A14 | c.1485G>T p.L495F | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.149); catalogued as COSV55735414; called by muse, mutect2, varscan2
- MTR | c.1953+1G>A p.X651_splice | Splice Site (SNP) | VAF 53/173 reads (31%) | catalogued as COSV63965151; called by muse, mutect2, varscan2
- MUC16 | c.29101G>T p.E9701* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV67471782; called by muse, mutect2, varscan2
- MUC17 | c.2558C>A p.T853N | Missense Mutation (SNP) | VAF 128/527 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs140905069, COSV60279818, COSV60291102; called by muse, varscan2
- MUC17 | c.9928A>T p.T3310S | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.899); catalogued as COSV60291109; called by muse, mutect2, varscan2
- MUC5B | c.6803C>A p.P2268Q | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV71591851, COSV71592642; called by muse, mutect2, varscan2
- MYH4 | c.3046A>G p.M1016V | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs558061741, COSV55119507; called by muse, mutect2, varscan2
- MYH9 | c.4814G>T p.R1605L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53386981, COSV53387531; called by muse, mutect2, varscan2
- MYT1L | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs200175227, COSV101219201; called by muse, mutect2, varscan2
- MZT2A | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.202); catalogued as COSV58312037; called by muse, mutect2, varscan2
- NAV3 | c.5038A>T p.T1680S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV57084908; called by muse, mutect2, varscan2
- NBEA | c.5017A>G p.T1673A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.017); catalogued as rs770598892, COSV59790676; called by muse, mutect2, varscan2
- NCKAP5 | c.5360T>C p.I1787T | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV58448665; called by muse, mutect2, varscan2
- NEFH | c.2337C>A p.D779E | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs748229404, COSV60217897; called by muse, varscan2
- NEK5 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as COSV62880324; called by muse, mutect2, varscan2
- NEUROD1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54549662; called by muse, mutect2, varscan2
- NEUROD4 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472076; called by muse, mutect2, varscan2
- NEUROG3 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV54343113; called by muse, mutect2, varscan2
- NF1 | c.2712T>A p.C904* | Nonsense Mutation (SNP) | VAF 98/164 reads (60%) | catalogued as COSV62206228; called by muse, varscan2
- NKAIN2 | c.193-2A>T p.X65_splice | Splice Site (SNP) | VAF 90/282 reads (32%) | catalogued as COSV63666261; called by muse, mutect2, varscan2
- NLRP14 | c.1468A>G p.M490V | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as rs757248652, COSV55067885; called by muse, mutect2, varscan2
- NMUR2 | c.969C>A p.N323K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54920005; called by muse, mutect2, varscan2
- NOD2 | c.2902C>T p.Q968* | Nonsense Mutation (SNP) | VAF 36/152 reads (24%) | catalogued as COSV56051596; called by muse, mutect2, varscan2
- NONO | c.340A>C p.I114L | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV52138044; called by muse, mutect2, varscan2
- NOVA1 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57478459, COSV99948177; called by muse, mutect2, varscan2
- NPFFR2 | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.115); catalogued as COSV58150514; called by muse, mutect2, varscan2
- NPR1 | c.2091C>A p.A697= | Splice Region (SNP) | VAF 22/61 reads (36%) | catalogued as COSV64117672; called by muse, mutect2, varscan2
- NXPE1 | c.574C>A p.L192I (on ENST00000424269; = p.L50I on NM_152315.5) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52630021; called by muse, mutect2, varscan2
- NYNRIN | c.5592G>T p.W1864C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101230642, COSV66841170; called by mutect2, varscan2
- OCRL | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV63981056; called by muse, mutect2
- OLFM4 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV54577875; called by muse, mutect2, varscan2
- OPALIN | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV64520642; called by muse, mutect2, varscan2
- OR10G3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57810479; called by muse, mutect2, varscan2
- OR10G7 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100389993; called by muse, mutect2, varscan2
- OR10G9 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100901684; called by muse, mutect2
- OR10J3 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV59954503; called by muse, mutect2, varscan2
- OR10Z1 | c.737C>G p.T246R | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs767358853, COSV100778929, COSV63523961; called by muse, mutect2, varscan2
- OR12D3 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65828353; called by muse, mutect2, varscan2
- OR2F2 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 115/402 reads (29%) | catalogued as rs776294986, COSV68832898; called by muse, mutect2, varscan2
- OR2F2 | c.343del p.L115Wfs*3 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | catalogued as COSV68832801; called by mutect2, pindel, varscan2
- OR2T4 | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63544173, COSV63545029; called by muse, mutect2, varscan2
- OR2T6 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63216473; called by muse, mutect2, varscan2
- OR4C13 | c.721del p.H241Tfs*17 | Frame Shift Del (DEL) | VAF 56/263 reads (21%) | catalogued as COSV73648759; called by mutect2, pindel, varscan2
- OR4D5 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV58307415, COSV58310111; called by muse, mutect2, varscan2
- OR4F6 | c.753T>A p.F251L | Missense Mutation (SNP) | VAF 92/460 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61026967; called by muse, mutect2, varscan2
- OR51B4 | c.810del p.I271Lfs*3 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | catalogued as COSV66517705; called by mutect2, pindel, varscan2
- OR51I2 | c.848T>A p.V283E | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58298980; called by muse, mutect2, varscan2
- OR5B12 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56905322; called by muse, mutect2, varscan2
- OR5B17 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as COSV62160437; called by muse, mutect2, varscan2
- OR5B2 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56908485; called by muse, mutect2, varscan2
- OR6K2 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV62743586; called by muse, mutect2, varscan2
- OR6T1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.173); catalogued as COSV58307424; called by muse, mutect2, varscan2
- OR6V1 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV69237334; called by muse, mutect2, varscan2
- OR7E24 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV71702193; called by muse, mutect2, varscan2
- OR8A1 | c.889A>G p.K297E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV52508929; called by muse, mutect2, varscan2
- OR8J1 | c.41T>A p.L14H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57318628; called by muse, mutect2, varscan2
- OR9G4 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV57248824; called by muse, mutect2, varscan2
- PAN2 | c.2633A>T p.Y878F (on ENST00000425394 / NM_001127460.3; = p.Y874F on NM_014871.5) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV57754258; called by muse, mutect2, varscan2
- PAPOLB | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV68201452; called by muse, mutect2, varscan2
- PAQR9 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61418356; called by muse, mutect2, varscan2
- PAX2 | c.954C>A p.N318K (on ENST00000428433 / NM_003987.5; = p.N295K on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV62291382; called by muse, mutect2, varscan2
- PCBP3 | c.813A>T p.L271F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV68408361; called by muse, mutect2
- PCDH11X | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as COSV53472820; called by muse, mutect2, varscan2
- PCDH11X | c.3539C>A p.A1180D | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as rs1037236865, COSV53472846; called by muse, mutect2, varscan2
- PCDH11X | c.3760G>C p.A1254P | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53472857; called by muse, mutect2, varscan2
- PCDH15 | c.4591G>T p.E1531* | Nonsense Mutation (SNP) | VAF 44/143 reads (31%) | catalogued as COSV57284690, COSV57325635; called by muse, mutect2, varscan2
- PCDH15 | c.4590G>T p.K1530N | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.062); catalogued as COSV100213564, COSV57325654; called by muse, mutect2, varscan2
- PCDH15 | c.2479C>A p.L827I | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as COSV57325671, COSV57402722; called by muse, mutect2, varscan2
- PCDH7 | c.1381A>C p.T461P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV62339766; called by muse, mutect2, varscan2
- PCDH9 | c.3039T>C p.C1013= | Splice Region (SNP) | VAF 34/63 reads (54%) | catalogued as COSV60556458; called by muse, mutect2, varscan2
- PCDHB1 | c.1704C>A p.N568K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV60629843, COSV60631383; called by muse, mutect2, varscan2
- PCDHB15 | c.1833G>T p.E611D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.714); catalogued as COSV99179039; called by muse, mutect2, varscan2
- PCDHGB2 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.616); catalogued as rs761837286, COSV53963343; called by muse, mutect2, varscan2
- PCNX1 | c.3388A>T p.I1130F | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV53095785; called by muse, mutect2, varscan2
- PCNX2 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV50810162; called by muse, mutect2, varscan2
- PCYT1B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV63265191; called by muse, mutect2, varscan2
- PDE1C | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV68811217; called by muse, mutect2
- PDE4DIP | c.4317G>C p.E1439D | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV57699965; called by muse, mutect2, varscan2
- PDZRN4 | c.2260C>G p.R754G (on ENST00000402685 / NM_001164595.2; = p.R496G on NM_013377.4) | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV54202580; called by muse, mutect2, varscan2
- PEX5 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV56955562; called by muse, mutect2, varscan2
- PGK2 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV59164142; called by muse, mutect2, varscan2
- PHTF2 | c.2063G>T p.G688V (on ENST00000248550 / NM_001366089.1; = p.G650V on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50328035; called by muse, mutect2, varscan2
- PI16 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV65448272; called by muse, mutect2, varscan2
- PIP4K2A | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as COSV60541224; called by muse, mutect2, varscan2
- PLD5 | c.700G>T p.G234C (on ENST00000442594; = p.G172C on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59138637; called by muse, varscan2
- PLD5 | c.691G>T p.V231L (on ENST00000442594; = p.V169L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs763027203, COSV59149326; called by muse, varscan2
- PLEKHG4B | c.1732G>C p.G578R (on ENST00000283426; = p.G934R on NM_052909.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52048780; called by muse, mutect2, varscan2
- PLP2 | c.203T>G p.M68R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV66239955; called by muse, mutect2
- PLPPR4 | c.1288A>G p.R430G | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV64566187, COSV64566380; called by muse, mutect2, varscan2
- PLSCR2 | c.356T>C p.I119T (on ENST00000497985 / NM_001199978.1; = p.I46T on NM_020359.2) | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60861742; called by muse, mutect2
- PLXNB3 | c.4018G>T p.A1340S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV62797925, COSV62799405; called by muse, mutect2, varscan2
- PNMA5 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs782263228, COSV62625728; called by muse, mutect2
- POLQ | c.6202A>G p.N2068D | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV51753673; called by muse, mutect2, varscan2
- POTEH | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 112/916 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100625091; called by muse, varscan2
- PPP1R16B | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55378729; called by muse, mutect2, varscan2
- PRDM9 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV57001893; called by muse, mutect2, varscan2
- PRKCI | c.801A>T p.K267N | Missense Mutation (SNP) | VAF 164/279 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55519550; called by muse, mutect2, varscan2
- PROSER1 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs759164768, COSV61487906; called by muse, mutect2, varscan2
- PRR30 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV53206537; called by muse, mutect2, varscan2
- PRRG1 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV66157813; called by muse, mutect2, varscan2
- PTCHD1 | c.800T>A p.V267E | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1359131084, COSV65059821; called by muse, mutect2, varscan2
- PTPRB | c.5732C>A p.T1911N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242777; called by muse, mutect2, varscan2
- PTPRZ1 | c.4394G>A p.S1465N | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV66438173; called by muse, mutect2, varscan2
- R3HDM1 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51525877; called by muse, mutect2, varscan2
- RAB41 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs908074553, COSV52104265; called by muse, mutect2, varscan2
- RALGAPB | c.2687A>T p.K896M | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53438682; called by muse, mutect2, varscan2
- RALGPS2 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.157); catalogued as COSV61337496; called by muse, mutect2, varscan2
- RANBP2 | c.2603T>G p.V868G | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51702355; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV52863078; called by muse, mutect2, varscan2
- RASAL1 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV55656736; called by muse, mutect2, varscan2
- RASEF | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs748122897, COSV64587387, COSV64588993; called by muse, mutect2, varscan2
- RDH12 | c.171A>C p.R57S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.438); catalogued as COSV50821938; called by muse, mutect2, varscan2
- REG1A | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52069344, COSV52069971; called by muse, mutect2, varscan2
- RNF144A | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); catalogued as COSV100305870; called by muse, mutect2, varscan2
- ROBO3 | c.3165G>A p.W1055* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs766739452, COSV67300913; called by muse, mutect2, varscan2
- ROCK1 | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 255/438 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV67696470; called by muse, mutect2, varscan2
- RP1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55118474; called by muse, mutect2, varscan2
- RPAP1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58539820; called by muse, mutect2, varscan2
- RSPH6A | c.1445G>C p.R482P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139803225, COSV55572286; called by muse, mutect2, varscan2
- RSPO2 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV52645946, COSV52655529; called by muse, mutect2, varscan2
- RSPO2 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52645953; called by muse, mutect2, varscan2
- RSPO2 | c.159C>G p.S53R | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV52645959; called by muse, mutect2, varscan2
- RTL9 | c.3425G>T p.G1142V | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101511664, COSV71825690; called by muse, mutect2, varscan2
- RXFP1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57051109; called by muse, mutect2, varscan2
- RYR2 | c.3915C>A p.S1305R | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV63689772; called by muse, mutect2, varscan2
- RYR2 | c.13466A>T p.Q4489L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV63689780; called by muse, mutect2, varscan2
- RYR3 | c.8511A>T p.L2837F (on ENST00000389232; = p.L2838F on NM_001036.6) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV66793479; called by muse, mutect2, varscan2
- SACS | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV101207532, COSV66541104; called by muse, mutect2, varscan2
- SAGE1 | c.1432A>G p.R478G | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV61014180; called by muse, varscan2
- SALL1 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV51758777; called by muse, mutect2, varscan2
- SAP30BP | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 157/357 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as rs1180193870, COSV53128338; called by muse, mutect2, varscan2
- SCN11A | c.4372C>T p.P1458S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV56571670; called by muse, mutect2, varscan2
- SEC16A | c.2968A>G p.T990A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1382979627, COSV51529893; called by muse, mutect2, varscan2
- SECISBP2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV60528874; called by muse, varscan2
- SELENOT | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101517720; called by muse, varscan2
- SEMA3D | c.1661G>A p.W554* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | catalogued as COSV52395315; called by muse, mutect2, varscan2
- SETD4 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59772442; called by muse, mutect2, varscan2
- SETD5 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV56711952; called by muse, mutect2, varscan2
- SIM1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53493070; called by muse, mutect2, varscan2
- SKOR1 | c.2501C>A p.A834E | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.081); catalogued as COSV58246694; called by muse, mutect2, varscan2
- SLC17A8 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100035263, COSV60124300; called by muse, mutect2, varscan2
- SLC17A8 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60124310; called by muse, mutect2, varscan2
- SLC30A8 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 85/268 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV69968129, COSV69971420; called by muse, mutect2, varscan2
- SLC44A1 | c.862del p.A288Pfs*14 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | catalogued as COSV58267317; called by mutect2, pindel, varscan2
- SLC44A5 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.286); catalogued as COSV63766750; called by muse, mutect2, varscan2
- SLC4A10 | c.276T>C p.F92= | Splice Region (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55782379; called by muse, mutect2, varscan2
- SLC4A5 | c.2542A>G p.M848V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781071671, COSV61028580; called by muse, mutect2, varscan2
- SLC8A1 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60478530; called by muse, mutect2, varscan2
- SLC8A3 | c.1890G>T p.A630= (on ENST00000381269 / NM_183002.3; = p.A631= on NM_033262.4) | Splice Region (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53690196; called by muse, mutect2, varscan2
- SLC9A7 | c.1165T>C p.C389R | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60380745; called by muse, mutect2
- SLC9A9 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV57230342, COSV57246609; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1988G>A p.W663* (on ENST00000540229 / NM_001371097.1; = p.W602* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 140/435 reads (32%) | catalogued as rs1198776295, COSV67444897; called by muse, mutect2, varscan2
- SLCO5A1 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | catalogued as COSV52653064, COSV52660853; called by muse, mutect2, varscan2
- SLITRK3 | c.1848C>A p.H616Q | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs35378268, COSV53849181; called by muse, mutect2
- SMAD1 | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57471626; called by muse, mutect2, varscan2
- SMC3 | c.2632G>T p.A878S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.057); catalogued as COSV62420515; called by muse, mutect2, varscan2
- SOGA3 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1212259311, COSV64105164, COSV64108272; called by muse, mutect2, varscan2
- SOX2 | c.133A>T p.M45L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57621768; called by muse, mutect2, varscan2
- SPAG1 | c.2533C>G p.L845V | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778546131, COSV52560420; called by muse, mutect2, varscan2
- SPAG17 | c.4685A>G p.K1562R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV60460590; called by muse, mutect2, varscan2
- SPAG17 | c.4423C>T p.Q1475* | Nonsense Mutation (SNP) | VAF 50/176 reads (28%) | catalogued as COSV60460596; called by muse, mutect2, varscan2
- SPANXN5 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100973988, COSV64968778; called by muse, mutect2, varscan2
- SPDYC | c.571C>G p.H191D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65865285; called by muse, mutect2, varscan2
- SPHKAP | c.4424C>T p.A1475V | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.272); catalogued as COSV60882195; called by muse, mutect2, varscan2
- SPHKAP | c.4022C>G p.P1341R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV60882204; called by muse, mutect2, varscan2
- SPTB | c.3461G>A p.G1154D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs751235570, COSV67632529; called by muse, mutect2, varscan2
- SRGAP1 | c.1721A>G p.N574S | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV61899022; called by muse, mutect2, varscan2
- SSPOP | n.11720C>G | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV65128680, COSV65131415; called by muse, mutect2, varscan2
- STAMBP | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763938839, COSV59897513; called by muse, mutect2, varscan2
- STAT1 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63116439; called by muse, mutect2
- STAT5A | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756814024, COSV61806971; called by muse, mutect2, varscan2
- STC1 | c.308T>A p.V103D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV51688800; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2494G>T p.V832L | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100562046; called by muse, mutect2, varscan2
- STRIP1 | c.2266+2T>A p.X756_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV63930667; called by muse, mutect2, varscan2
- STS | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54268889; called by muse, mutect2, varscan2
- SUN1 | c.2104C>T p.P702S (on ENST00000405266 / NM_001367651.1; = p.P582S on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67450084; called by muse, mutect2, varscan2
- SYT10 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1433911858, COSV57341335; called by muse, varscan2
- TAB3 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55837610; called by muse, mutect2, varscan2
- TADA1 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63309791; called by muse, mutect2, varscan2
- TAF1 | c.676G>T p.G226* (on ENST00000373790 / NM_138923.4; = p.G247* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV52115451; called by muse, varscan2
- TAP2 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66487912; called by muse, mutect2, varscan2
- TBC1D31 | c.2108T>C p.L703S | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54867071; called by muse, mutect2, varscan2
- TBC1D7 | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.508); catalogued as COSV58244209; called by muse, mutect2, varscan2
- TBC1D7 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58244214; called by muse, mutect2, varscan2
- TCF23 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV56078525; called by muse, mutect2, varscan2
- TCTEX1D1 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51075926; called by muse, mutect2, varscan2
- TENT5A | c.824T>A p.L275H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788436; called by muse, mutect2, varscan2
- TEX11 | c.974T>A p.V325D (on ENST00000344304; = p.V310D on NM_031276.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV60232138; called by muse, mutect2, varscan2
- TEX13A | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV61161582; called by muse, varscan2
- TEX55 | c.1555A>T p.N519Y | Missense Mutation (SNP) | VAF 109/761 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55211375; called by muse, mutect2, varscan2
- TFAP2D | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as COSV50421210; called by muse, mutect2, varscan2
- TFDP1 | c.383A>C p.Q128P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV64740725; called by muse, mutect2, varscan2
- TGIF2LX | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV52214194; called by muse, mutect2, varscan2
- THBS2 | c.1894G>T p.V632F | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV64679463; called by muse, mutect2, varscan2
- TIAM1 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54554792; called by muse, mutect2, varscan2
- TIE1 | c.1260C>G p.D420E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV65249991; called by muse, mutect2, varscan2
- TLE1 | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV64721416; called by muse, varscan2
- TMCO5A | c.607C>G p.H203D | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1324157645, COSV60464992; called by muse, mutect2, varscan2
- TMEM132D | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV67160677; called by muse, mutect2, varscan2
- TMEM163 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV56107889; called by muse, mutect2, varscan2
- TMEM26 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53262510; called by muse, mutect2, varscan2
- TMEM72 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV67460648; called by muse, mutect2, varscan2
- TNN | c.2892G>T p.K964N | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53427942; called by muse, mutect2, varscan2
- TNR | c.1743C>A p.N581K | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.965); catalogued as rs758748473, COSV54889946, COSV54891930; called by muse, mutect2, varscan2
- TPR | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV66602020; called by muse, mutect2, varscan2
- TRIB3 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV53931600; called by muse, mutect2, varscan2
- TRMT2B | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58619778; called by muse, mutect2, varscan2
- TRPM6 | c.1698G>T p.Q566H | Missense Mutation (SNP) | VAF 128/385 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.084); catalogued as COSV62512906; called by muse, mutect2, varscan2
- TSC22D3 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV59778086; called by muse, mutect2, varscan2
- TTC5 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV51871127; called by muse, mutect2
- TTN | c.31372C>T p.P10458S (on ENST00000591111; = p.P9531S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV60112358; called by muse, mutect2
- TTN | c.21506C>G p.S7169C (on ENST00000591111; = p.S6242C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | PolyPhen possibly damaging (0.518); catalogued as rs879108235, COSV60112372; called by muse, mutect2, varscan2
- TUBA3C | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV67139417; called by muse, mutect2, varscan2
- TYR | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.941); catalogued as rs199500520, COSV54477366, COSV99635530; called by muse, mutect2, varscan2
- UBR7 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV50149855; called by muse, mutect2, varscan2
- UGT3A2 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1285924410, COSV56931079; called by muse, mutect2, varscan2
- UNC13A | c.2257G>T p.V753L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV53198039; called by muse, mutect2, varscan2
- USH2A | c.6677G>T p.C2226F | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56381176; called by muse, mutect2, varscan2
- USP11 | c.1205A>T p.Q402L (on ENST00000218348; = p.Q359L on NM_001371072.1) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54474025; called by muse, mutect2
- USP33 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV62469809; called by muse, mutect2, varscan2
- VCAM1 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV54119857; called by muse, mutect2, varscan2
- VIM | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV56406102; called by muse, varscan2
- VPS13C | c.6148G>T p.V2050L (on ENST00000644861 / NM_020821.3; = p.V2007L on NM_017684.5) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51219224; called by muse, mutect2, varscan2
- WDR33 | c.1948C>A p.Q650K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV59249933; called by muse, mutect2, varscan2
- WDR38 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62019111; called by muse, mutect2, varscan2
- WDR4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV57733921; called by muse, mutect2, varscan2
- WDR49 | c.1351-2A>G p.X451_splice (on ENST00000308378 / NM_001366158.1; = p.X792_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 64/239 reads (27%) | catalogued as COSV57709587; called by muse, mutect2, varscan2
- WFIKKN2 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV60959020; called by muse, mutect2, varscan2
- WIPF3 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54209477; called by muse, mutect2, varscan2
- WWP1 | c.1061+1G>T p.X354_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | catalogued as COSV55360032; called by muse, mutect2, varscan2
- WWTR1 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV62291561; called by muse, mutect2, varscan2
- XAGE3 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.19); catalogued as COSV100655660, COSV60569118; called by muse, mutect2, varscan2
- XPNPEP2 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64369254; called by muse, mutect2, varscan2
- YAF2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV59891407; called by muse, mutect2, varscan2
- ZBBX | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 208/381 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV56791550; called by muse, mutect2, varscan2
- ZBTB4 | c.2715C>A p.D905E | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV60140661; called by muse, mutect2, varscan2
- ZFHX4 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV50967493; called by muse, mutect2, varscan2
- ZFHX4 | c.6852T>A p.S2284R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV50968033; called by muse, mutect2, varscan2
- ZFR | c.2704G>T p.A902S | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.997); catalogued as COSV54050332, COSV54053878; called by muse, mutect2, varscan2
- ZFYVE1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV59611442; called by muse, mutect2, varscan2
- ZFYVE26 | c.5253C>G p.H1751Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs772349907, COSV61329446; called by muse, mutect2, varscan2
- ZMAT4 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as COSV52701716, COSV52713141; called by muse, mutect2
- ZNF112 | c.2121C>A p.Y707* (on ENST00000337401 / NM_001083335.2; = p.Y701* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as COSV61620315; called by muse, mutect2, varscan2
- ZNF189 | c.922A>G p.R308G | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52275515; called by muse, mutect2, varscan2
- ZNF236 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53490022; called by muse, mutect2, varscan2
- ZNF324B | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.56); catalogued as COSV60742147; called by muse, mutect2, varscan2
- ZNF331 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV53477354; called by muse, mutect2, varscan2
- ZNF398 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60065535; called by muse, mutect2, varscan2
- ZNF398 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60065539; called by muse, mutect2, varscan2
- ZNF415 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54702050; called by muse, mutect2
- ZNF423 | c.1417A>G p.K473E (on ENST00000563137 / NM_001379286.1; = p.K465E on NM_015069.4) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV52191407; called by muse, mutect2, varscan2
- ZNF470 | c.1934G>C p.G645A | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV57969230, COSV57971256; called by muse, mutect2, varscan2
- ZNF527 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV62231125; called by muse, mutect2, varscan2
- ZNF536 | c.1091T>A p.M364K | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62825819; called by muse, mutect2, varscan2
- ZNF638 | c.227A>T p.H76L | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52488740; called by muse, mutect2, varscan2
- ZNF711 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs3747423, COSV52151473, COSV52156210; called by muse, mutect2, varscan2
- ZNF721 | c.2558A>G p.Y853C (on ENST00000338977; = p.Y865C on NM_133474.4) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59093371; called by muse, mutect2, varscan2
- ZNF808 | c.1901G>T p.W634L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV63120176; called by muse, mutect2, varscan2
- ZNF808 | c.1902G>T p.W634C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.382); catalogued as rs1431107132, COSV63120182; called by muse, mutect2, varscan2
- ZNF813 | c.1626T>G p.H542Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV67176777; called by muse, mutect2
- ZSCAN31 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 108/347 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV60180989; called by muse, mutect2, varscan2
- ZSWIM3 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV54848249; called by muse, mutect2, varscan2
- BOD1L1 | c.4606G>T p.G1536W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BRD2 | c.1235dup p.E413Gfs*5 | Frame Shift Ins (INS) | VAF 62/265 reads (23%) | called by mutect2, pindel, varscan2
- CDH9 | c.783delinsGA p.N262Kfs*15 | Frame Shift Ins (INS) | VAF 61/441 reads (14%) | called by pindel, varscan2*
- ERCC6 | c.935del p.N312Tfs*17 | Frame Shift Del (DEL) | VAF 92/314 reads (29%) | called by mutect2, pindel, varscan2
- FUT9 | c.223_224del p.Q75Dfs*3 | Frame Shift Del (DEL) | VAF 33/149 reads (22%) | called by mutect2, pindel, varscan2
- GRIN3B | c.1203del p.S402Lfs*19 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- IGLV7-43 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KIR3DL2 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.093); called by muse, mutect2
- LRRC34 | c.439del p.L147Ffs*10 | Frame Shift Del (DEL) | VAF 44/249 reads (18%) | called by mutect2, pindel*, varscan2
- MAP4 | c.2944del p.A982Qfs*13 | Frame Shift Del (DEL) | VAF 51/137 reads (37%) | called by mutect2, pindel, varscan2
- MMP28 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAP1L3 | c.1420_1421insT p.D474Vfs*2 | Frame Shift Ins (INS) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- NDST4 | c.375dup p.G126Rfs*9 | Frame Shift Ins (INS) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- NFE2L3 | c.1192_1202del p.A398Qfs*3 | Frame Shift Del (DEL) | VAF 33/202 reads (16%) | called by mutect2, pindel, varscan2
- OR2B3 | c.295del p.A99Pfs*9 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- OR4A5 | c.708del p.C237Afs*32 | Frame Shift Del (DEL) | VAF 35/127 reads (28%) | called by mutect2, pindel, varscan2
- PCDHGB3 | c.2003dup p.L668Ffs*7 | Frame Shift Ins (INS) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- POTEA | c.1350G>C p.M450I (on ENST00000519951 / NM_001005365.2; = p.M404I on NM_001002920.1) | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRDM13 | c.1460del p.G487Afs*4 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- PTPN4 | c.963del p.F321Lfs*7 | Frame Shift Del (DEL) | VAF 90/416 reads (22%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.451del p.V151* | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D3B | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 54/666 reads (8%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.764); called by muse, varscan2
- TBX5 | c.231del p.K78Rfs*12 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- TPTE | c.907A>T p.M303L (on ENST00000618007 / NM_199261.4; = p.M285L on NM_199259.4) | Missense Mutation (SNP) | VAF 19/674 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- TRBV27 | c.95C>G p.T32R | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- WDR72 | c.2684del p.L895Cfs*7 | Frame Shift Del (DEL) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- AATF | c.726C>T p.I242= | Silent (SNP) | VAF 22/231 reads (10%) | called by muse, mutect2, varscan2
- ABCA3 | c.756A>G p.A252= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1163826019, COSV57054735; called by muse, mutect2, varscan2
- ACSM2A | c.1608C>G p.A536= (on ENST00000219054; = p.A457= on NM_001308169.2) | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV54585550; called by muse, mutect2
- ACSS1 | c.1080T>C p.F360= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV60221104; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2004A>T p.I668= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV54451562; called by muse, mutect2, varscan2
- ADCY8 | c.3126C>G p.A1042= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- ALDH1L1 | c.2682G>T p.R894= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56410931; called by muse, mutect2, varscan2
- ALX1 | c.204C>A p.T68= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV57492621; called by muse, mutect2, varscan2
- ANGEL2 | c.1293A>G p.Q431= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV64737494; called by muse, mutect2, varscan2
- ANKK1 | c.1458C>T p.D486= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- ANKLE1 | c.1626C>A p.G542= (on ENST00000394458; = p.G488= on NM_152363.6) | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV66731343, COSV66732703; called by muse, mutect2, varscan2
- ANKRD30A | c.576G>A p.L192= (on ENST00000611781; = p.L136= on NM_052997.2) | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as rs1250316051, COSV100654757, COSV64612248; called by muse, mutect2
- ANO3 | c.2220T>C p.D740= | Silent (SNP) | VAF 48/169 reads (28%) | catalogued as rs1442733168, COSV56794059; called by muse, mutect2, varscan2
- ASPM | c.6288A>T p.T2096= | Silent (SNP) | VAF 63/222 reads (28%) | catalogued as COSV54131126; called by muse, mutect2, varscan2
- BBS7 | c.2005A>C p.R669= | Silent (SNP) | VAF 84/220 reads (38%) | catalogued as COSV52657050; called by muse, mutect2, varscan2
- BCL11A | c.2178C>T p.H726= (on ENST00000335712 / NM_001365609.1; = p.H760= on NM_022893.4) | Silent (SNP) | VAF 64/758 reads (8%) | catalogued as COSV59631254; called by muse, mutect2
- BCL11B | c.675A>G p.T225= (on ENST00000357195 / NM_001282237.2; = p.T154= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61736089; called by muse, mutect2, varscan2
- BPNT1 | c.42C>T p.S14= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as rs758908259, COSV59040152; called by muse, varscan2
- BRCA2 | c.4434A>G p.L1478= | Silent (SNP) | VAF 101/210 reads (48%) | catalogued as rs786201411, COSV66455053; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRINP2 | c.1744C>T p.L582= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100838565, COSV64177946; called by muse, mutect2, varscan2
- C1QC | c.243C>A p.P81= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV65889644; called by muse, mutect2, varscan2
- CAGE1 | c.2118A>G p.T706= (on ENST00000512086; = p.T570= on NM_205864.3) | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as rs1561857047, COSV57078023; called by muse, mutect2, varscan2
- CCDC141 | c.2223T>A p.V741= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV55375209; called by muse, mutect2, varscan2
- CCDC144A | c.258A>G p.R86= | Silent (SNP) | VAF 51/260 reads (20%) | catalogued as COSV61403609; called by muse, mutect2, varscan2
- CCNB1 | c.579G>C p.L193= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV56510292, COSV99841310; called by muse, mutect2, varscan2
- CDKL2 | c.939A>G p.L313= | Silent (SNP) | VAF 95/230 reads (41%) | catalogued as COSV56733798; called by muse, mutect2, varscan2
- CEMIP | c.1911C>A p.T637= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV54994202; called by muse, mutect2, varscan2
- CEP152 | c.2871G>C p.R957= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV57860227; called by muse, mutect2, varscan2
- CEP162 | c.1887G>C p.A629= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57620527, COSV57624727; called by muse, mutect2, varscan2
- CES5A | c.1431C>T p.A477= (on ENST00000290567 / NM_001143685.2; = p.A427= on NM_145024.3) | Silent (SNP) | VAF 72/278 reads (26%) | catalogued as COSV51867150; called by muse, mutect2, varscan2
- CFHR5 | c.21A>T p.V7= | Silent (SNP) | VAF 67/213 reads (31%) | catalogued as COSV56822770; called by muse, mutect2, varscan2
- COL4A2 | c.1800A>G p.P600= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV64629192; called by muse, mutect2, varscan2
- CPNE4 | c.843C>A p.G281= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as COSV70195151; called by muse, mutect2, varscan2
- DDX60 | c.3642A>G p.L1214= | Silent (SNP) | VAF 132/287 reads (46%) | catalogued as COSV67097102; called by muse, mutect2, varscan2
- DEFA3 | c.138C>A p.S46= | Silent (SNP) | VAF 30/382 reads (8%) | catalogued as COSV100590621, COSV100590645; called by muse, mutect2
- DEFB118 | c.54C>T p.I18= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs746093758, COSV53620517, COSV53621583; called by muse, mutect2, varscan2
- DHCR7 | c.1054C>A p.R352= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as CM980552, COSV62795574, COSV62796171; called by muse, mutect2, varscan2
- DIDO1 | c.2553C>T p.L851= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs1204338575, COSV56624901; called by muse, mutect2, varscan2
- DLC1 | c.4453A>C p.R1485= (on ENST00000276297 / NM_001348081.2; = p.R1048= on NM_006094.5) | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs371211456; called by muse, mutect2, varscan2
- DMAP1 | c.1239C>G p.G413= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV60000866; called by muse, mutect2
- ECT2 | c.1146T>G p.R382= (on ENST00000392692 / NM_001349098.2; = p.R351= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/292 reads (7%) | catalogued as COSV51689759; called by muse, mutect2
- ELF4 | c.1284G>T p.L428= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV57452958; called by muse, mutect2
- F8 | c.4455C>A p.A1485= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV64274445; called by muse, mutect2
- FBXL14 | c.510C>A p.R170= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV59336554; called by muse, mutect2, varscan2
- FCRL3 | c.309C>A p.I103= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV63842136; called by muse, mutect2, varscan2
- FLNB | c.7779T>C p.P2593= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV55881878; called by muse, mutect2, varscan2
- GAB2 | c.766C>A p.R256= (on ENST00000361507 / NM_080491.3; = p.R218= on NM_012296.3) | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV60868518; called by muse, mutect2, varscan2
- GALNTL6 | c.468C>A p.L156= | Silent (SNP) | VAF 81/176 reads (46%) | catalogued as rs757453245, COSV71828951, COSV71831490; called by muse, mutect2, varscan2
- GCKR | c.384G>A p.L128= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV53021760; called by muse, mutect2, varscan2
- GEMIN7 | c.351G>T p.A117= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV54319822, COSV99541513; called by muse, mutect2, varscan2
- GJA1 | c.141T>C p.D47= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV56998213; called by muse, mutect2, varscan2
- GJA8 | c.372G>T p.P124= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53789149, COSV53790561; called by muse, mutect2, varscan2
- GPR173 | c.153T>C p.R51= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV60235396; called by muse, mutect2, varscan2
- GRM1 | c.906C>T p.A302= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV51163630; called by muse, mutect2, varscan2
- GRM5 | c.984G>A p.K328= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV59605609; called by muse, mutect2, varscan2
- GSPT2 | c.1110G>T p.L370= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV61214501; called by muse, mutect2, varscan2
- IARS2 | c.2037T>C p.V679= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV56960382; called by muse, mutect2, varscan2
- IGKV1-39 | c.18C>A p.P6= | Silent (SNP) | VAF 7/57 reads (12%) | called by mutect2, varscan2
- IHH | c.1050C>T p.A350= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs747612055, COSV55393166; called by muse, mutect2, varscan2
- IMMP2L | c.291A>G p.E97= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs1267113526, COSV59244214; called by muse, mutect2, varscan2
- IQUB | c.1356A>G p.R452= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV61239831; called by muse, mutect2, varscan2
- IRAK1 | c.618C>A p.S206= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV57654415; called by muse, mutect2
- ITGB4 | c.3676C>T p.L1226= | Silent (SNP) | VAF 65/335 reads (19%) | catalogued as COSV52327183; called by muse, mutect2, varscan2
- KCNA4 | c.1467C>A p.V489= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV60252866; called by muse, mutect2, varscan2
- KIAA0408 | c.1512C>A p.P504= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100846989, COSV64106484; called by muse, mutect2, varscan2
- KIF4B | c.213G>T p.P71= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV70527220, COSV70529755; called by muse, mutect2, varscan2
- LAMP2 | c.1053G>A p.R351= | Silent (SNP) | VAF 22/192 reads (11%) | catalogued as COSV52353446; called by muse, mutect2, varscan2
- LAS1L | c.1578G>T p.G526= | Silent (SNP) | VAF 31/171 reads (18%) | catalogued as COSV56707641; called by muse, mutect2, varscan2
- LBR | c.1173C>T p.P391= | Silent (SNP) | VAF 95/268 reads (35%) | catalogued as rs764872060, CD021830, COSV55289397; called by muse, mutect2, varscan2
- LILRA2 | c.477A>G p.E159= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as COSV52192492; called by muse, mutect2, varscan2
- LRRFIP1 | c.1830G>A p.Q610= (on ENST00000392000 / NM_001137552.2; = p.Q586= on NM_004735.4) | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV55252672; called by muse, mutect2, varscan2
- LRRIQ1 | c.3444A>T p.S1148= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV67832035; called by muse, mutect2, varscan2
- LTF | c.1905A>G p.Q635= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV51608764; called by muse, mutect2, varscan2
- MAN1C1 | c.1293G>A p.G431= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV56045632; called by muse, mutect2, varscan2
- MAP3K13 | c.1623A>G p.K541= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV53990137; called by muse, mutect2
- MCM10 | c.813C>A p.G271= (on ENST00000484800 / NM_182751.3; = p.G270= on NM_018518.5) | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV66334857; called by muse, mutect2, varscan2
- MGAM | c.2400A>G p.Q800= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV72074822; called by muse, mutect2
- MICAL1 | c.2847C>T p.G949= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs376575225, COSV57805287, COSV57805670; called by muse, mutect2, varscan2
- MOGAT3 | c.351G>A p.G117= | Silent (SNP) | VAF 53/173 reads (31%) | catalogued as COSV56174853; called by muse, mutect2, varscan2
- MPP3 | c.1161G>T p.L387= | Silent (SNP) | VAF 190/304 reads (63%) | catalogued as COSV68198393; called by muse, mutect2, varscan2
- MUC2 | c.2781G>A p.T927= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- MYO18B | c.588T>C p.S196= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1417661131, COSV59136676; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO5A | c.171G>A p.K57= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV62561003; called by muse, mutect2, varscan2
- MYO7A | c.921G>T p.V307= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV68685012; called by muse, mutect2, varscan2
- MYPN | c.126C>T p.C42= | Silent (SNP) | VAF 101/201 reads (50%) | catalogued as COSV62734737; called by muse, mutect2, varscan2
- MYPN | c.3582C>T p.R1194= | Silent (SNP) | VAF 76/391 reads (19%) | catalogued as rs139820597, COSV100590294; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK2 | c.1212C>G p.L404= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV65356175; called by muse, mutect2, varscan2
- NOD2 | c.2901C>A p.L967= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV56051582, COSV56052886, COSV56052914; called by muse, mutect2, varscan2
- NPAP1 | c.798C>T p.A266= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs766319160, COSV61507768; called by muse, mutect2, varscan2
- NRK | c.1945C>A p.R649= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54598361, COSV54601851; called by muse, mutect2, varscan2
- OR10A2 | c.633C>A p.A211= | Silent (SNP) | VAF 75/288 reads (26%) | catalogued as COSV100224894, COSV56299607; called by muse, mutect2, varscan2
- OR1A1 | c.375C>A p.A125= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV58403920; called by muse, mutect2, varscan2
- OR1C1 | c.765C>A p.A255= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV68715808; called by muse, mutect2, varscan2
- OR4C16 | c.858G>T p.T286= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100114231, COSV58942344, COSV58943104; called by muse, mutect2, varscan2
- OR4K15 | c.414C>T p.L138= (on ENST00000305051; = p.L114= on NM_001005486.1) | Silent (SNP) | VAF 63/256 reads (25%) | catalogued as COSV59301802; called by muse, mutect2, varscan2
- OR6M1 | c.123C>A p.I41= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV58433845; called by muse, mutect2, varscan2
- OR6T1 | c.594G>T p.V198= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs771301550, COSV58307434; called by muse, mutect2, varscan2
- OR8J3 | c.345G>T p.L115= | Silent (SNP) | VAF 66/210 reads (31%) | catalogued as rs377708276, COSV56880577; called by muse, mutect2, varscan2
- P2RX3 | c.36C>A p.T12= | Silent (SNP) | VAF 100/341 reads (29%) | catalogued as COSV53479898; called by muse, mutect2, varscan2
- PEX1 | c.1986T>C p.D662= | Silent (SNP) | VAF 93/334 reads (28%) | catalogued as rs747406256, COSV50400540; called by muse, mutect2, varscan2
- PGAM2 | c.147G>A p.K49= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV51978487; called by muse, mutect2, varscan2
- PGBD1 | c.1281T>C p.F427= | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as COSV52553817; called by muse, mutect2, varscan2
- PIGS | c.1155G>A p.V385= | Silent (SNP) | VAF 98/176 reads (56%) | catalogued as COSV52024860; called by muse, mutect2, varscan2
- PNN | c.1914G>T p.R638= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV53766793; called by muse, mutect2, varscan2
- PUS7 | c.1770A>G p.A590= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV62676995; called by muse, mutect2, varscan2
- RAI14 | c.597C>T p.N199= | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as rs143309351; called by muse, mutect2
- REG3G | c.528G>A p.*176= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as COSV55448691, COSV55449992; called by muse, mutect2
- RGPD2 | c.3942T>C p.S1314= | Silent (SNP) | VAF 34/86 reads (40%) | called by mutect2, varscan2
- RIC1 | c.2734C>T p.L912= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV52610429; called by muse, mutect2, varscan2
- RNMT | c.1413C>G p.A471= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV51085649; called by muse, mutect2, varscan2
- RTL4 | c.816C>A p.A272= | Silent (SNP) | VAF 69/146 reads (47%) | catalogued as COSV61206631; called by muse, mutect2, varscan2
- RXFP2 | c.1182C>A p.P394= | Silent (SNP) | VAF 51/236 reads (22%) | catalogued as COSV53641345; called by muse, mutect2, varscan2
- SCAF8 | c.513C>G p.V171= | Silent (SNP) | VAF 15/238 reads (6%) | catalogued as COSV65792139; called by muse, mutect2
- SCML2 | c.1647A>T p.L549= | Silent (SNP) | VAF 57/257 reads (22%) | catalogued as COSV52621864; called by muse, mutect2, varscan2
- SEC16B | c.1821G>T p.T607= | Silent (SNP) | VAF 67/252 reads (27%) | catalogued as COSV100381138, COSV57626558; called by muse, mutect2, varscan2
- SEMA3D | c.411C>T p.P137= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV52395326; called by muse, mutect2, varscan2
- SERPINA4 | c.612C>T p.D204= | Silent (SNP) | VAF 66/230 reads (29%) | catalogued as rs371042106; called by muse, mutect2, varscan2
- SIX1 | c.720C>T p.H240= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs759290962, COSV55959523; called by muse, mutect2, varscan2
- SLC12A3 | c.1230C>T p.T410= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52635668; called by muse, mutect2, varscan2
- SLC12A8 | c.2112C>T p.L704= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs200565283; called by muse, mutect2, varscan2
- SLC1A5 | c.768C>A p.I256= | Silent (SNP) | VAF 71/203 reads (35%) | catalogued as COSV69467040, COSV69467470; called by muse, mutect2, varscan2
- SLC24A3 | c.1194A>T p.T398= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV60121544; called by muse, mutect2, varscan2
- SLC5A6 | c.441G>C p.V147= | Silent (SNP) | VAF 165/577 reads (29%) | catalogued as COSV60159841; called by muse, mutect2, varscan2
- SLCO1A2 | c.1065C>A p.I355= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as COSV100262447, COSV56603998; called by muse, mutect2, varscan2
- SLIT2 | c.1176T>C p.F392= | Silent (SNP) | VAF 65/211 reads (31%) | catalogued as COSV56575545; called by muse, mutect2, varscan2
- SOGA1 | c.729G>T p.R243= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV52920800; called by muse, mutect2, varscan2
- SPATA31E1 | c.1968T>A p.P656= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV57792447; called by muse, mutect2, varscan2
- SPDYC | c.222C>T p.F74= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs375301773; called by muse, mutect2, varscan2
- SPTB | c.4299G>A p.E1433= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as COSV67632528; called by muse, mutect2, varscan2
- SREBF2 | c.3141C>T p.P1047= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs757074741, COSV63331504; called by muse, mutect2, varscan2
- TAS2R1 | c.378C>T p.V126= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs867677795, COSV66778780; called by muse, mutect2, varscan2
- TBX20 | c.897T>C p.S299= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV68783939; called by muse, mutect2, varscan2
- TFAP2D | c.1146C>A p.I382= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV50421312; called by muse, mutect2, varscan2
- TLR8 | c.1254C>T p.S418= (on ENST00000218032 / NM_138636.5; = p.S436= on NM_016610.4) | Silent (SNP) | VAF 49/204 reads (24%) | catalogued as COSV54318512, COSV54320711; called by muse, mutect2, varscan2
- TMC1 | c.1464G>A p.K488= | Silent (SNP) | VAF 164/508 reads (32%) | catalogued as COSV52777096; called by muse, mutect2, varscan2
- TMEM123 | c.480A>G p.K160= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV63444110; called by muse, varscan2
- TMEM132E | c.750G>C p.V250= (on ENST00000321639; = p.V340= on NM_001304438.2) | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV58697717; called by muse, mutect2, varscan2
- TMEM39B | c.561C>T p.S187= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs200377497, COSV60379458; called by muse, mutect2, varscan2
- TPM2 | c.327C>G p.A109= | Silent (SNP) | VAF 159/233 reads (68%) | catalogued as COSV61406368; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1515G>A p.E505= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV100967094, COSV64853031; called by muse, mutect2, varscan2
- TTN | c.19674A>G p.A6558= (on ENST00000591111; = p.A5631= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs753049407, COSV60112387; called by muse, mutect2, varscan2
- UNC5D | c.1590C>A p.I530= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as COSV54800856, COSV54805853; called by muse, mutect2, varscan2
- VIM | c.1017C>A p.S339= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV56406092, COSV99813413; called by muse, varscan2
- WARS1 | c.234A>G p.T78= | Silent (SNP) | VAF 66/275 reads (24%) | catalogued as COSV59925837; called by muse, mutect2, varscan2
- WDR20 | c.195C>A p.L65= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV54470982, COSV54472611, COSV54475638; called by muse, mutect2, varscan2
- ZC4H2 | c.594G>T p.R198= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV62004072; called by muse, mutect2, varscan2
- ZEB2 | c.2334C>T p.S778= | Silent (SNP) | VAF 113/368 reads (31%) | catalogued as COSV57958192; called by muse, mutect2, varscan2
- ZGRF1 | c.843A>G p.K281= | Silent (SNP) | VAF 94/213 reads (44%) | catalogued as COSV52201110; called by muse, mutect2, varscan2
- ZIC2 | c.1260G>A p.Q420= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV66255033; called by muse, mutect2, varscan2
- ZMAT1 | c.336T>C p.H112= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV65658831; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500351 A>C | 5'Flank (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- C6orf118 | c.*1C>T | 3'UTR (SNP) | VAF 33/101 reads (33%) | catalogued as rs780395167, COSV100024772; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33807C>G | Intron (SNP) | VAF 50/171 reads (29%) | catalogued as COSV57774271; called by muse, mutect2, varscan2
- CIRBP | c.-7+491G>A | Intron (SNP) | VAF 19/48 reads (40%) | catalogued as COSV58012698; called by muse, mutect2, varscan2
- COPS9 | chr2:240126695 C>A | 3'Flank (SNP) | VAF 112/173 reads (65%) | catalogued as COSV56228318; called by muse, mutect2, varscan2
- DLG2 | c.205-65720del | Intron (DEL) | VAF 48/220 reads (22%) | called by mutect2, pindel, varscan2
- DNAH8 | chr6:38723077 C>A | 5'Flank (SNP) | VAF 32/119 reads (27%) | catalogued as rs960018798, COSV100546362; called by muse, mutect2, varscan2
- IAPP | c.-2C>A | 5'UTR (SNP) | VAF 19/119 reads (16%) | catalogued as rs1190095246, COSV99557133; called by muse, mutect2, varscan2
- IAPP | c.-1A>C | 5'UTR (SNP) | VAF 19/122 reads (16%) | catalogued as rs1321713715, COSV99557134; called by muse, mutect2, varscan2
- MAGEA4 | c.-97G>T | 5'UTR (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99367519, COSV99367617; called by muse, mutect2, varscan2
- NALCN | c.1765-4834C>A | Intron (SNP) | VAF 24/150 reads (16%) | catalogued as COSV51973205; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1551G>T | RNA (SNP) | VAF 49/165 reads (30%) | catalogued as rs374724969; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163855 G>A | 5'Flank (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- SNORD115-39 | n.58G>T | RNA (SNP) | VAF 116/387 reads (30%) | called by muse, mutect2, varscan2
- SNORD116-12 | n.74C>A | RNA (SNP) | VAF 30/109 reads (28%) | catalogued as rs1186384686; called by muse, mutect2, varscan2
- TCF3 | c.1823-388G>T | Intron (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99514315; called by muse, mutect2, varscan2
- TTN | c.10361-4016G>A | Intron (SNP) | VAF 65/287 reads (23%) | catalogued as rs1383177370, COSV60112400; called by muse, mutect2, varscan2
